Somatic mutation profile of tumor specimen 0DIPLE from CCDI case PBBWDW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.6 years (2,046 days).
Specimen 0DIPLE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4705ef50-45f9-4567-aa3c-4f77f651a3e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIPKU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53fcee96-8cd6-4c96-8538-04198d5feeee

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Frame Shift Ins 2, 5'Flank 1, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.3575G>A p.R1192H | Missense Mutation (SNP) | VAF 163/568 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60785906, COSV60794673; called by muse, mutect2, varscan2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 44/236 reads (19%) | catalogued as rs754199513; called by mutect2, varscan2
- KRTAP4-9 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 60/390 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.611); catalogued as rs759618050, COSV66949573; called by muse, mutect2
- SDK1 | c.1604C>T p.S535L | Missense Mutation (SNP) | VAF 99/421 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs746455785, COSV67365149; called by muse, mutect2, varscan2
- SLC22A18 | c.1177G>A p.V393I | Missense Mutation (SNP) | VAF 138/539 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.234); catalogued as rs139693015; called by muse, mutect2, varscan2
- DYNC1H1 | c.12905G>C p.R4302P | Missense Mutation (SNP) | VAF 76/247 reads (31%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- F8 | c.654dup p.A219Cfs*4 | Frame Shift Ins (INS) | VAF 95/423 reads (22%) | called by mutect2, varscan2
- GSE1 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 93/331 reads (28%) | called by muse, mutect2, varscan2
- ZNF536 | c.1673_1690dup p.L558_K563dup | In Frame Ins (INS) | VAF 44/176 reads (25%) | called by mutect2, varscan2
- DOCK6 | c.2043G>A p.P681= | Silent (SNP) | VAF 111/514 reads (22%) | catalogued as rs373707024; called by muse, mutect2, varscan2
- FKBP10 | c.1236C>T p.D412= | Silent (SNP) | VAF 104/678 reads (15%) | catalogued as rs372633492; called by muse, mutect2, varscan2
- MECR | c.534C>T p.F178= | Silent (SNP) | VAF 121/441 reads (27%) | catalogued as rs757514440, COSV55284120, COSV99746893; called by muse, mutect2, varscan2
- STK3 | c.600T>C p.C200= | Silent (SNP) | VAF 118/531 reads (22%) | called by muse, mutect2, varscan2
- BICD2 | chr9:92764815 C>T | 5'Flank (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
